Somatic mutation profile of tumor specimen C3L-02212-01 (aliquot CPT0389450006) from CPTAC case C3L-02212, project CPTAC-3 (Kidney — Transitional Cell Papillomas and Carcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Urothelial carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.5 years (25,745 days).
Specimen C3L-02212-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aa47a14-1323-48c4-8dbe-7b722a153c80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02212-31 (Blood Derived Normal), aliquot CPT0389550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/130bf7bc-8943-41be-9ce9-60f6ebceca57

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Intron 2, Splice Region 2, 5'Flank 2, Frame Shift Del 1, 3'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 41/200 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV67263286, COSV67263499; called by muse, mutect2, varscan2
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 126/234 reads (54%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHRNE | c.804C>T p.A268= | Splice Region (SNP) | VAF 155/476 reads (33%) | catalogued as rs775149431, COSV99544793; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR52J3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs754756527, COSV66746561; called by muse, mutect2
- PCDHA8 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 104/869 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100969259; called by muse, mutect2, varscan2
- PCDHB13 | c.2144G>T p.R715M | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV53395267; called by muse, mutect2
- PDGFRB | c.936G>A p.E312= | Splice Region (SNP) | VAF 19/105 reads (18%) | catalogued as rs1367367619; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR12 | c.3643G>T p.G1215W (on ENST00000615927; = p.G2036W on NM_020719.3) | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV101330663; called by muse, varscan2
- PRR35 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs758647792, COSV53464836; called by muse, mutect2, varscan2
- RTCA | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1001603550, COSV53120052; called by muse, mutect2, varscan2
- SLC38A10 | c.2884C>T p.R962W | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs768753318; called by muse, mutect2, varscan2
- SLC5A8 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs747375853, COSV73310648; called by muse, mutect2, varscan2
- SNAP91 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 17/318 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs369146791; called by muse, mutect2
- WBP4 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs776551815; called by muse, mutect2, varscan2
- WWC3 | c.2270C>G p.S757C | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1480086584, COSV101081921; called by muse, mutect2, varscan2
- ACACA | c.5143A>G p.I1715V | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CC2D2B | c.225A>C p.E75D | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX17 | c.1430T>G p.V477G | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.5215G>T p.A1739S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- DNASE2B | c.240G>C p.M80I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK1 | c.2759C>A p.S920Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- IGLON5 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGLV2-11 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 26/581 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2
- LATS1 | c.2363del p.G788Vfs*3 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- OGFR | c.1419T>A p.S473R | Missense Mutation (SNP) | VAF 157/323 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PKHD1L1 | c.7276_7308del p.G2426_Q2436del | In Frame Del (DEL) | VAF 51/100 reads (51%) | called by mutect2, pindel
- PRSS38 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SMTNL2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- TLN1 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- UBE3A | c.2470A>C p.K824Q | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF544 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 128/307 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C1orf127 | c.1905G>A p.E635= | Silent (SNP) | VAF 92/196 reads (47%) | catalogued as rs1371135100; called by muse, mutect2, varscan2
- COL9A3 | c.1626G>A p.A542= | Silent (SNP) | VAF 26/405 reads (6%) | catalogued as rs756770871, COSV58984021; called by muse, mutect2
- EHBP1 | c.978A>G p.P326= | Silent (SNP) | VAF 62/236 reads (26%) | called by muse, mutect2, varscan2
- HBA2 | c.204C>G p.T68= | Silent (SNP) | VAF 52/787 reads (7%) | called by muse, mutect2
- KCNH5 | c.2562C>T p.T854= | Silent (SNP) | VAF 66/153 reads (43%) | called by muse, mutect2, varscan2
- NUDT10 | c.351A>G p.R117= | Silent (SNP) | VAF 135/180 reads (75%) | catalogued as rs1557312385; called by muse, mutect2, varscan2
- OR8H2 | c.231C>T p.V77= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs746011343; called by muse, mutect2, varscan2
- PLD5 | c.1578C>T p.D526= (on ENST00000442594; = p.D464= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/243 reads (7%) | catalogued as rs369388309; called by muse, mutect2
- PRR5 | c.144C>T p.N48= (on ENST00000336985 / NM_181333.4; = p.N39= on NM_015366.4) | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as rs774376034; called by muse, mutect2
- TRAF7 | c.564C>T p.C188= | Silent (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- ZBTB16 | c.312T>C p.Y104= | Silent (SNP) | VAF 125/486 reads (26%) | catalogued as rs978300998; called by muse, mutect2, varscan2
- BRD4 | c.2158+635C>G | Intron (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- MAML3 | c.2079+58G>A | Intron (SNP) | VAF 146/334 reads (44%) | catalogued as rs1443934072, COSV59077094; called by muse, varscan2
- PLEKHA2 | c.*811C>G | 3'UTR (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- ST13P4 | n.622G>A | RNA (SNP) | VAF 87/293 reads (30%) | catalogued as rs763796810; called by muse, mutect2, varscan2
- SYCE1 | chr10:133567899 C>T | 5'Flank (SNP) | VAF 20/59 reads (34%) | catalogued as rs548235150; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451425 G>A | 5'Flank (SNP) | VAF 10/120 reads (8%) | catalogued as rs1452848842; called by muse, mutect2
